Somatic mutation profile of tumor specimen TCGA-14-0790-01B (aliquot TCGA-14-0790-01B-01W-0837-08) from TCGA case TCGA-14-0790, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.8 years (23,674 days).
Specimen TCGA-14-0790-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d12f7ef-5d7e-4fc9-bcd4-f68d219792bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0790-10A (Blood Derived Normal), aliquot TCGA-14-0790-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9bf788-25ee-4d1c-902a-3d00a8e61cfb

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Splice Region 3, Frame Shift Ins 3, In Frame Del 1, Nonsense Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 1865/1980 reads (94%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918641, CM900201, CM910357, COSV100935723, COSV63748619; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.2104G>A p.V702M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.407); catalogued as rs370096577; called by muse, mutect2, varscan2
- ADGRG4 | c.8648C>A p.T2883N | Missense Mutation (SNP) | VAF 121/224 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV54956478; called by muse, mutect2, varscan2
- AHNAK2 | c.13331G>A p.R4444Q | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.034); catalogued as rs781458836, COSV60915782; called by muse, mutect2, varscan2
- ARID4A | c.3041A>G p.D1014G | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV62163832; called by muse, mutect2, varscan2
- ARMC10 | c.935T>C p.L312S | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747289552, COSV100085583; called by muse, mutect2, varscan2
- ASZ1 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs1214750928, COSV52913027; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 38/328 reads (12%) | catalogued as rs745882580; called by mutect2, varscan2
- BCAR3 | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs759045700, COSV53075135; called by muse, mutect2, varscan2
- CD58 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs764273333, COSV59841507, COSV59841764; called by muse, mutect2, varscan2
- COPB1 | c.1213-2A>T p.X405_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as rs753555066; called by mutect2, varscan2
- CRYBB2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 156/399 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1388838236, COSV68005482; called by muse, mutect2, varscan2
- CTDP1 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.668); catalogued as rs746584267, COSV50003490; called by muse, mutect2, varscan2
- DPP10 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 151/262 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1055873408, COSV59686211; called by muse, mutect2, varscan2
- EPO | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs201069425, COSV53161447, COSV99402559; called by muse, mutect2, varscan2
- FAM47C | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1215954460, COSV63726680; called by muse, varscan2
- GLIPR1 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 96/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758483406, COSV56991052; called by muse, mutect2, varscan2
- GRIN2A | c.3206C>T p.T1069M | Missense Mutation (SNP) | VAF 181/435 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.832); catalogued as rs777249842, COSV58032094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HARBI1 | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 106/225 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV56319503; called by muse, mutect2, varscan2
- HPSE | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 95/191 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60986866; called by muse, mutect2, varscan2
- HROB | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV55369693; called by muse, mutect2, varscan2
- IL18RAP | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51826052, COSV51828701; called by muse, mutect2, varscan2
- KIDINS220 | c.606T>C p.N202= | Splice Region (SNP) | VAF 57/95 reads (60%) | catalogued as COSV56753677; called by muse, mutect2, varscan2
- LAMB1 | c.4111C>T p.Q1371* | Nonsense Mutation (SNP) | VAF 41/1747 reads (2%) | catalogued as COSV55964765; called by muse, mutect2
- LEFTY2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV64746954; called by muse, mutect2, varscan2
- LGR4 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs1462234311, COSV64864416; called by muse, mutect2, varscan2
- MATK | c.446C>A p.S149Y (on ENST00000310132 / NM_139355.3; = p.S150Y on NM_002378.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59554629; called by muse, mutect2, varscan2
- MYH4 | c.348C>T p.Y116= | Splice Region (SNP) | VAF 129/317 reads (41%) | catalogued as rs750137859, COSV55118524; called by muse, mutect2, varscan2
- PIK3R1 | c.658A>T p.I220F | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs756172158, COSV57130454; called by muse, mutect2, varscan2
- PLCB2 | c.3073C>G p.Q1025E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV53033738; called by muse, mutect2, varscan2
- PRPF8 | c.3440T>C p.V1147A | Missense Mutation (SNP) | VAF 124/278 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59263528; called by muse, mutect2, varscan2
- RNASE11 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 205/524 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV60087650; called by muse, mutect2, varscan2
- RPL5 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59873502; called by muse, mutect2, varscan2
- RTP1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs372732386; called by muse, mutect2, varscan2
- SCML2 | c.90G>A p.R30= | Splice Region (SNP) | VAF 19/56 reads (34%) | catalogued as COSV52621153, COSV99318528; called by muse, mutect2, varscan2
- SLC27A2 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757049403, COSV51057903, COSV51059226; called by muse, mutect2, varscan2
- SPAG17 | c.2159T>A p.L720Q | Missense Mutation (SNP) | VAF 203/476 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.568); catalogued as COSV60459203; called by muse, mutect2, varscan2
- TIAM2 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1327087529, COSV51637628; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1892A>G p.K631R | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.621); catalogued as COSV54437735; called by muse, mutect2
- UROC1 | c.161dup p.D55Gfs*30 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | catalogued as rs764241328; called by pindel, varscan2
- VIPR2 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs754896998, COSV51117658; called by muse, mutect2, varscan2
- VPS39 | c.1799C>T p.A600V (on ENST00000348544 / NM_001301138.2; = p.A589V on NM_015289.5) | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58789715; called by muse, mutect2, varscan2
- ZFP42 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1052462774, COSV58817514; called by muse, mutect2, varscan2
- ZNF608 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60437937; called by muse, mutect2, varscan2
- ZPBP | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.019); catalogued as rs148913753; called by muse, mutect2, varscan2
- NR1H2 | c.913dup p.A305Gfs*64 | Frame Shift Ins (INS) | VAF 38/187 reads (20%) | called by mutect2, pindel, varscan2
- S1PR1 | c.777_779del p.I260del | In Frame Del (DEL) | VAF 140/318 reads (44%) | called by mutect2, pindel, varscan2
- SRA1 | c.293T>C p.V98A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP6 | c.2196C>T p.F732= (on ENST00000337414 / NM_013427.3; = p.F529= on NM_013423.3) | Silent (SNP) | VAF 101/200 reads (51%) | catalogued as rs774954368, COSV57296165; called by muse, mutect2, varscan2
- BCORL1 | c.2517G>A p.A839= | Silent (SNP) | VAF 83/180 reads (46%) | catalogued as rs201695526, COSV54396660; called by muse, mutect2, varscan2
- CDADC1 | c.1483A>C p.R495= | Silent (SNP) | VAF 153/367 reads (42%) | catalogued as rs1217564894, COSV51911567; called by muse, mutect2, varscan2
- CYP8B1 | c.459G>A p.T153= | Silent (SNP) | VAF 99/251 reads (39%) | catalogued as rs777771086, COSV60226414; called by muse, mutect2, varscan2
- FBXO38 | c.372G>A p.E124= | Silent (SNP) | VAF 377/857 reads (44%) | catalogued as COSV57028009; called by muse, mutect2, varscan2
- GRM1 | c.3129C>A p.T1043= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV51151045; called by muse, mutect2, varscan2
- KIR2DL1 | c.201C>T p.N67= | Silent (SNP) | VAF 420/2813 reads (15%) | catalogued as rs144426670; called by muse, mutect2, varscan2
- KRT3 | c.1209G>A p.T403= | Silent (SNP) | VAF 53/166 reads (32%) | catalogued as rs753687170, COSV58815067, COSV58815686; called by muse, mutect2, varscan2
- LIMS1 | c.609C>T p.R203= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs111779374, COSV57540379; called by muse, mutect2, varscan2
- METTL21C | c.189C>T p.Y63= | Silent (SNP) | VAF 84/199 reads (42%) | catalogued as rs140891650; called by muse, mutect2, varscan2
- MYLK | c.4131G>A p.T1377= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs756697460, COSV60610605; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTKN2 | c.1740C>A p.T580= | Silent (SNP) | VAF 60/74 reads (81%) | catalogued as COSV59522495; called by muse, mutect2, varscan2
- SBNO1 | c.3360G>A p.A1120= (on ENST00000420886; = p.A1119= on NM_018183.5) | Silent (SNP) | VAF 249/537 reads (46%) | catalogued as rs773765202, COSV57341816; called by muse, mutect2, varscan2
- SPAG17 | c.1716T>G p.T572= | Silent (SNP) | VAF 221/490 reads (45%) | catalogued as COSV60459209; called by muse, mutect2, varscan2
- TMEM132E | c.2301G>A p.P767= (on ENST00000321639; = p.P857= on NM_001304438.2) | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- VPS9D1 | c.366C>G p.L122= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as rs1175853562, COSV57068361; called by muse, mutect2, varscan2
- ZNF618 | c.201C>T p.P67= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs1216611853, COSV55921710; called by muse, mutect2, varscan2
- ZSCAN1 | c.1080C>T p.S360= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs144381428; called by muse, mutect2, varscan2
- WDR44 | c.112-882T>C | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99561122, COSV99561818; called by muse, mutect2, varscan2
